CGCI case BLGSP-71-19-00123 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b22261d6-12e3-464d-99cb-da3ae8ba6ba6

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 11 years; Vital status: Dead; Days to death: 112 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 11.2 years (4,088 days); Year of diagnosis: 2002; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 70 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Bone marrow; Sites of involvement: Bone marrow.
   Pathology details: Bone marrow malignant cells: Yes.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 0, day 70.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD10: Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Negative.
- CD3: Negative.
- MYC translocation (FISH): Positive.

Other clinical attributes
- Day 0: Weight: 23 kg; Height: 119 cm; BMI: 16.2.
- Day 0: Risk factors: Ataxia-Telangiectasia.
- Day 0: Comorbidities: Ataxia-Telangiectasia.

Biospecimens (4 samples)
- Samples BLGSP-71-19-00123-01Z, BLGSP-71-19-00123-09Z (2 with the same recorded description): Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00123-09A.1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Sorted Cells; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Aspirate; Tissue collection type: Retrospective.
- Sample BLGSP-71-19-00123-16A: Sample type: Mononuclear Cells from Bone Marrow Normal; Tissue type: Normal; Specimen type: Mononuclear Cells from Bone Marrow; Preservation method: Frozen; Days to sample procurement: 7 days; Method of sample procurement: Bone Marrow Aspirate; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: History immunological disease other: ataxia-telangiectasia.
- Primary pathology: Histologic diagnosis: ALL - L3; Extranodal site involvement: 1; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD3.
